Somatic mutation profile of tumor specimen C3N-00148-01 (aliquot CPT0081580009) from CPTAC case C3N-00148, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.9 years (19,314 days).
Specimen C3N-00148-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2b12462-d9c9-4983-9b25-8bf28e788e99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00148-71 (Blood Derived Normal), aliquot CPT0081700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28e7bec3-0928-4e6b-9691-dac8d9074bd9

The open-access MAF lists 115 somatic variants for this specimen: 79 protein-altering or splice-affecting, 21 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 21, Frame Shift Del 10, Intron 6, 3'UTR 4, 5'UTR 4, Nonsense Mutation 2, Frame Shift Ins 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.350G>A p.W117* | Nonsense Mutation (SNP) | VAF 86/236 reads (36%) | hotspot (GDC flag); catalogued as rs1559428056, CM141838, CM961425, COSV56542825, COSV56544265, COSV56548887; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGXT2 | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 100/523 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV51491132; called by muse, mutect2, varscan2
- ASH1L | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV64209445; called by muse, mutect2, varscan2
- CDYL | c.1210G>A p.D404N (on ENST00000328908 / NM_001368125.1; = p.D350N on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59359308; called by muse, mutect2
- DPY19L1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs762478422, COSV60581164; called by muse, mutect2, varscan2
- FCAR | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 87/367 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV62029575; called by muse, mutect2, varscan2
- FCRL2 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100830047, COSV63834967; called by muse, mutect2
- GOSR2 | c.266G>T p.R89L (on ENST00000393456 / NM_001321134.1; = p.R107L on NM_004287.5) | Missense Mutation (SNP) | VAF 65/431 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV56662540; called by muse, mutect2, varscan2
- KCNJ3 | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99715379; called by muse, mutect2, varscan2
- MGAT1 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 160/375 reads (43%) | PolyPhen probably damaging (0.992); catalogued as rs1311974324, COSV57135272; called by muse, mutect2, varscan2
- NT5E | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs374757389; called by muse, mutect2, varscan2
- PARVG | c.144+7C>A | Splice Region (SNP) | VAF 11/172 reads (6%) | catalogued as rs1350051072; called by muse, mutect2
- PCNX4 | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1331372813; called by muse, mutect2
- PIGV | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.778); catalogued as COSV50290595; called by muse, mutect2, varscan2
- RYR2 | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.177); catalogued as rs780931894; called by muse, mutect2, varscan2
- RYR3 | c.10105G>T p.A3369S (on ENST00000389232; = p.A3370S on NM_001036.6) | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.341); catalogued as COSV66791793; called by muse, mutect2, varscan2
- TENM4 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as COSV53669886; called by muse, mutect2, varscan2
- TRPM4 | c.1815C>G p.D605E | Missense Mutation (SNP) | VAF 60/401 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53264035; called by muse, mutect2, varscan2
- ACSF2 | c.852dup p.N285Qfs*11 | Frame Shift Ins (INS) | VAF 35/188 reads (19%) | called by mutect2, pindel, varscan2
- ADGRD2 | c.2904C>G p.D968E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- AKAP3 | c.2265del p.T756Rfs*2 | Frame Shift Del (DEL) | VAF 33/287 reads (11%) | called by mutect2, pindel, varscan2
- AMY2B | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 86/397 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ARHGEF19 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ARHGEF2 | c.2008G>T p.V670L (on ENST00000361247 / NM_001162383.2; = p.V642L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BSCL2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 92/428 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- BTNL9 | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 46/331 reads (14%) | called by muse, mutect2, varscan2
- C10orf71 | c.3680G>C p.R1227T | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- CCL19 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CYP3A5 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 24/499 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2
- DAP3 | c.811A>G p.R271G | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DDX20 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DES | c.1144del p.A382Pfs*13 | Frame Shift Del (DEL) | VAF 89/372 reads (24%) | called by mutect2, pindel, varscan2
- DESI1 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNM1 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DRAXIN | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DYNC2H1 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DYNLL2 | c.215A>T p.H72L | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FCN1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- FER | c.2143T>G p.S715A | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.987); called by muse, mutect2
- FNDC1 | c.5066G>C p.G1689A | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GREB1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYAL4 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- IGF2BP1 | c.935del p.I312Tfs*18 | Frame Shift Del (DEL) | VAF 35/140 reads (25%) | called by mutect2, pindel, varscan2
- ITM2B | c.774del p.F258Lfs*6 | Frame Shift Del (DEL) | VAF 54/314 reads (17%) | called by mutect2, pindel, varscan2
- KDM3B | c.2912T>A p.L971Q | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.2026A>T p.M676L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2
- MAN2B1 | c.2876A>G p.N959S | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MAP1A | c.7271G>T p.S2424I | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- METAP2 | c.189_190del p.V64Gfs*2 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | called by mutect2, pindel, varscan2
- MUTYH | c.1415G>C p.W472S | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NADSYN1 | c.1586A>T p.Y529F | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NCAPD3 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NDST1 | c.602del p.N201Tfs*9 | Frame Shift Del (DEL) | VAF 35/202 reads (17%) | called by mutect2, pindel, varscan2
- NME8 | c.1693G>C p.V565L | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); called by muse, mutect2
- OTOL1 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PBRM1 | c.2328del p.L776Ffs*2 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- PCDHA5 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 113/744 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PITPNM2 | c.1515del p.Q506Rfs*26 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | called by mutect2, pindel
- PKP4 | c.2298C>G p.N766K | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RNF138 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RNFT1 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RPRD2 | c.3389A>G p.D1130G | Missense Mutation (SNP) | VAF 73/298 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RSPH6A | c.1286T>C p.F429S | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SP3 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPTY2D1 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK38 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SUGT1 | c.295del p.L99* | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- TLR8 | c.1999A>T p.T667S (on ENST00000218032 / NM_138636.5; = p.T685S on NM_016610.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TMF1 | c.1463G>A p.R488K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2
- TNN | c.1355A>T p.D452V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- UNC13B | c.936A>T p.E312D | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- USPL1 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP4 | c.1578T>A p.N526K | Missense Mutation (SNP) | VAF 108/469 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VNN3 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); called by muse, mutect2
- WDR33 | c.3522del p.G1175Efs*106 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.5406C>G p.I1802M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF292 | c.6332A>C p.Y2111S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ZNF414 | c.508T>A p.Y170N | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNHIT2 | c.862dup p.H288Pfs*40 | Frame Shift Ins (INS) | VAF 31/161 reads (19%) | called by mutect2, pindel, varscan2
- ABCA13 | c.1038C>G p.V346= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV70045746; called by muse, mutect2, varscan2
- ADGRB2 | c.3474C>T p.C1158= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs1274144556, COSV99926696; called by muse, mutect2, varscan2
- AUTS2 | c.345G>A p.E115= | Silent (SNP) | VAF 43/311 reads (14%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.1869G>T p.R623= | Silent (SNP) | VAF 37/127 reads (29%) | called by muse, mutect2, varscan2
- CDYL | c.1209T>G p.L403= (on ENST00000328908 / NM_001368125.1; = p.L349= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- CNTNAP2 | c.3888C>T p.N1296= | Silent (SNP) | VAF 46/416 reads (11%) | catalogued as rs1460281368; called by muse, mutect2, varscan2
- DOCK7 | c.5382T>A p.V1794= (on ENST00000635253 / NM_001367561.1; = p.V1763= on NM_033407.3) | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- DST | c.2103C>G p.L701= (on ENST00000361203 / NM_001374722.1; = p.L375= on NM_001723.6) | Silent (SNP) | VAF 44/353 reads (12%) | catalogued as rs150530855; called by muse, mutect2, varscan2
- FAM161A | c.1392T>C p.H464= | Silent (SNP) | VAF 76/352 reads (22%) | called by muse, mutect2, varscan2
- HEPACAM | c.1065C>T p.I355= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1401A>G p.T467= | Silent (SNP) | VAF 25/278 reads (9%) | catalogued as rs1270220526; called by muse, mutect2
- KLHL11 | c.180C>T p.S60= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as rs782083223; called by muse, mutect2, varscan2
- MAPRE2 | c.6T>C p.P2= | Silent (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- MYH11 | c.4944C>T p.R1648= | Silent (SNP) | VAF 37/261 reads (14%) | called by muse, mutect2, varscan2
- REST | c.799T>C p.L267= | Silent (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- SELE | c.981C>T p.F327= | Silent (SNP) | VAF 14/260 reads (5%) | catalogued as rs1386945833, COSV60976143; called by muse, mutect2
- SORBS2 | c.2061G>A p.R687= | Silent (SNP) | VAF 98/422 reads (23%) | catalogued as rs775418076; called by muse, mutect2, varscan2
- TSPAN31 | c.108C>G p.G36= | Silent (SNP) | VAF 32/161 reads (20%) | called by muse, mutect2, varscan2
- VIT | c.1284C>A p.T428= (on ENST00000389975 / NM_001177969.1; = p.T443= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- ZNF521 | c.1785C>A p.I595= | Silent (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- ZNF676 | c.1467C>T p.A489= (on ENST00000650058; = p.A457= on NM_001001411.3) | Silent (SNP) | VAF 88/423 reads (21%) | catalogued as COSV68094387; called by muse, mutect2, varscan2
- AIP | c.-35C>A | 5'UTR (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- CEP41 | c.*4164G>T | 3'UTR (SNP) | VAF 48/460 reads (10%) | called by muse, mutect2, varscan2
- COLEC11 | c.130+1724G>T | Intron (SNP) | VAF 77/320 reads (24%) | called by muse, mutect2, varscan2
- DIS3L2 | c.602-19404A>G | Intron (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- IQGAP1 | c.-73G>C | 5'UTR (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- LINC00922 | n.925T>A | RNA (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- MDH2 | c.-50C>A | 5'UTR (SNP) | VAF 183/459 reads (40%) | catalogued as rs1554584381; called by muse, mutect2, varscan2
- NUP214 | c.-116G>A | 5'UTR (SNP) | VAF 14/61 reads (23%) | catalogued as rs184944546, COSV55988943; called by muse, mutect2, varscan2
- SEC23B | c.*48del | 3'UTR (DEL) | VAF 61/278 reads (22%) | called by mutect2, pindel, varscan2
- SFT2D1 | c.*44T>C | 3'UTR (SNP) | VAF 33/142 reads (23%) | catalogued as rs758972323; called by muse, mutect2, varscan2
- SYP | c.102+48G>T | Intron (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- TPT1 | c.102+234A>G | Intron (SNP) | VAF 48/279 reads (17%) | catalogued as rs1203014676; called by muse, mutect2, varscan2
- TRIM41 | c.909+19C>T | Intron (SNP) | VAF 30/215 reads (14%) | catalogued as rs367715726; called by muse, mutect2, varscan2
- VPS13A | c.100+24C>G | Intron (SNP) | VAF 28/193 reads (15%) | catalogued as COSV62424786; called by muse, mutect2, varscan2
- ZNF546 | c.*35G>T | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
